Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A3DG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A3DG-01A (Primary Tumor).

[page 1 of 2]
100-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54-1

lw
10/21/11

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, right and left ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy: FIGO grade 3 (of 3) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (1.8 x 1.3 x 1.3 cm) located in the right fundus of the uterine cavity. The tumor invades 0.7 cm into the myometrium (total wall thickness 1.7 cm) but does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. Tumor involves the surface of both ovaries and fallopian tubes, the posterior uterine serosa and cul de sac, and right and left adnexal soft tissues forming multiple nodular masses ranging in size from 0.3 cm to 5.2 cm in greatest dimension. There is also an 8.5 x 6.7 x 4.2 cm aggregate of detached tumor present.

B. Colon, sigmoid, segmental resection: Positive for metastatic adenocarcinoma forming multiple (approximately 20) serosal, nodular masses ranging in size from 0.5 cm to 11.5 cm in greatest dimension. The attached portion of omentum is also positive for metastatic adenocarcinoma forming multiple (5) nodular masses ranging in size from 1.0 cm to 3.5 cm in greatest dimension.

C. Omentum, omentectomy: Positive for metastatic adenocarcinoma forming multiple nodular masses ranging in size from 0.2 cm to 4.2 cm in greatest dimension.

With available surgical material [AJCC pT3a] (7th edition, 2010)

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left tube and ovaries" is a 160.0 gram uterus with attached bilateral fallopian tubes and left ovary. The posterior uterine serosa and cul de sac has a 5.2 x 4.3 x 1.0 cm tumor mass. There is a 1.8 x 1.3 x 1.3 cm polypoid mass in the right fundus of the endometrial cavity, grossly invading 0.7 cm. The myometrial thickness is 1.7 cm. There are no uterine leiomyomas. There is an 8.5 x 6.7 x 4.2 cm aggregate of detached tumor which contains and encases the right ovary (2.1 x 2.0 x 1.4 cm). The ovary contains a 1.5 x 1.2 x 1.2 cm right ovarian cyst. The attached right fallopian tube measures 6.5 x 0.6 cm. There is a 3.0 x 1.2 x 0.7 cm left ovary with a nodular outer surface and a solid cut surface with a 7.4 x 0.6 cm left fallopian tube. There are also multiple tumor nodules involving the surface of the left ovary, the surfaces of the left and right fallopian tubes, and in the right and left adnexal soft tissue (ranging in size from 0.3 cm to 1.2 cm in greatest dimension). Representative sections are submitted.

B. Received fresh labeled "sigmoid colon" is a 32.0 cm length portion of sigmoid colon that has multiple (approximately 20) red-pink irregular serosal nodules ranging in size from 0.5 cm to 11.5 cm in greatest dimension. The nodules appear to extend into the muscle, without involvement of the overlying mucosa. There is a scant portion of omentum that has multiple (5) nodules ranging in size from 1.0 cm to 3.5 cm in greatest dimension. The mucosa has approximately 63 diverticula. No gross perforation is identified.

[page 2 of 2]
Representative sections are submitted.

C. Received fresh labeled "omentum" is a 66.0 x 19.0 x 2.3 cm portion of omentum. There are multiple nodules ranging in size from 0.2 cm to 4.2 cm in greatest dimension. Lymph nodes are not identified. Representative sections are submitted.

IHPAA Discrepancy		/
Other Malignancy History		/

Source: NCI Genomic Data Commons file 2c9a2b3a-11b3-454c-8671-c34d16952083 (TCGA-D1-A3DG.97C44FFC-8D88-43DC-BCC9-F634151C7098.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).